Gene-level copy-number profile of tumor specimen ALCH-B1Y1-TTP1-A from ALCHEMIST case ALCH-B1Y1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.4 years (26,442 days).
Specimen ALCH-B1Y1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7a63dcb7-65c9-447b-bfe5-768dd828ae7e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1Y1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/904e4f7e-4a82-490a-a3e1-936f033c5d11

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 5,197; copy number 2: 53,585; copy number 3: 69; copy number 4: 5; copy number 9: 1; copy number 17: 2.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,424,776–6,466,175, 4 genes (within-gene range 0–1): ESPN, MIR4252, AL031848.1, TNFRSF25.
- chr1:43,525,187–43,623,666, 1 gene: PTPRF.
- chr2:131,794,961–131,836,532, 4 genes: CDRT15P3, AC103564.3, AC103564.1, AC103564.2.
- chr2:241,849,884–241,858,894, 1 gene: PDCD1.
- chr4:119,409,333–119,434,108, 2 genes: AC093752.3, RNU6-1217P.
- chr5:180,601,506–180,649,624, 1 gene: FLT4.
- chr6:35,497,874–35,512,896, 1 gene: TULP1.
- chr7:98,252,379–98,310,441, 1 gene (within-gene range 0–2): BRI3.
- chr10:47,995,322–47,999,791, 1 gene: FAM25C.
- chr10:50,676,743–50,686,326, 1 gene: NUTM2HP.
- chr14:99,500,190–99,604,207, 1 gene (within-gene range 0–3): CCDC85C.
- chr14:99,583,017–99,625,740, 2 genes: Y_RNA, AL160313.1.
- chr14:103,094,723–103,110,559, 2 genes: AL161669.1, EXOC3L4.
- chr16:70,661,204–70,686,053, 2 genes: MTSS2, AC020763.4.
- chr16:75,204,103–75,268,053, 5 genes: CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–2): SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr18:11,609,596–11,610,612, 1 gene: SLC35G4.
- chr18:45,825,675–45,844,094, 1 gene: SIGLEC15.
- chr19:416,583–460,996, 2 genes: SHC2, RNA5SP462.
- chr19:4,969,113–5,153,598, 1 gene: KDM4B.
- chr20:63,939,829–64,039,962, 8 genes (within-gene range 0–1): UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204.
- chr21:43,092,956–43,107,570, 1 gene: U2AF1.
- chr21:43,169,008–43,172,805, 1 gene: CRYAA.
- chr21:45,981,769–46,005,050, 1 gene: COL6A1.
- chr22:45,920,366–45,977,162, 1 gene (within-gene range 0–1): WNT7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,107,942–43,168,646, 1 gene, copy number 17 (within-gene range 1–17): AP001631.2.
- chr21:43,140,523–43,162,277, 2 genes, copy number 9–17: FRGCA, AP001631.1.

Autosomal genes at a single copy (total copy number 1): 2,349. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
